HCMI case HCM-SANG-0315-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/2127626f-247f-4c47-b096-a876f08db1a0

Demographics
Sex at birth: female; Days to birth: -26,480 days (72.5 years before the index date).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C25.3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Pancreatic duct; Classification of tumor: primary; Tumor grade: G2; Metastasis at diagnosis: No Metastasis; Uicc clinical stage: Stage IIA; Uicc pathologic m: M0; Uicc pathologic n: N0; Uicc pathologic stage: Stage IIA; Uicc pathologic t: T3; Uicc staging system edition: 7th.
   Pathology details: Peripancreatic lymph nodes positive: 0; Peripancreatic lymph nodes tested: 13.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Gemcitabine; Treatment intent type: Neoadjuvant; Days to treatment start: 208 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Neoadjuvant; Days to treatment start: 208 days.

Molecular and laboratory tests
- CA19-9: 13.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (5 samples)
- Sample HCM-SANG-0315-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-SANG-0315-C25-10A-01D-A80T-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample HCM-SANG-0315-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
- Samples HCM-SANG-0315-C25-85A-01D-A80T-32, HCM-SANG-0315-C25-85A-01R-A80W-32 (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
